Surgical pathology report (de-identified scan), TCGA case TCGA-BF-A3DM, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-A3DM-01A (Primary Tumor).

Case #: DOB: Sex: Male Ethnicity (Race)

Cancer Sample

Diagnosis: Melanoma Histological description: Melanoma

Date of Procurement: Anatomic Site: Skin Tumor location: Primary

Tissue Specification: Tumor Specimen Matrix: Tissue Specimen Format: Frozen

Container: cryomold Type of Procurement: Surgery Grade: 3

T Stage: 4 N Stage: 0 M Stage: 0 Treatment: no

Treatment Details: no/no

1CD-0-3
Melanoma, NOS 8720/3
Site: Skin, NOS C44.9

Normal Sample

Anatomic Site: Blood Sample Type: normal Type of Procurement: Blood draw

Matrix: Blood Specimen Format: Frozen Container: tube

Date of Procurement:

bw
10/15/11

Source: NCI Genomic Data Commons file 0688a2a8-4324-48fd-b3c3-eba17bc62cbc (TCGA-BF-A3DM.62947184-2FA4-4C16-B1DD-54C7C78293A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).